Somatic mutation profile of tumor specimen MMRF_2341_1_BM_CD138pos (aliquot MMRF_2341_1_BM_CD138pos_T2_KHS5U_K14039) from MMRF case MMRF_2341, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.7 years (19,625 days).
Specimen MMRF_2341_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc8e88ae-ff3b-422d-89ac-0191c5ff0885.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2341_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2341_1_PB_Whole_C1_KHS5U_K14038; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84bbcbd1-7591-48a9-afc4-912369ce1072

The open-access MAF lists 173 somatic variants for this specimen: 65 protein-altering or splice-affecting, 25 silent, 83 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, 3'UTR 46, Silent 25, Intron 22, 3'Flank 7, 5'UTR 6, Nonsense Mutation 3, Frame Shift Del 2, Translation Start Site 2, 5'Flank 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 20/204 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705661, COSV66706270; called by muse, mutect2
- ALOX5 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 59/118 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs750402256; called by muse, mutect2, varscan2
- ASB5 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV56674030; called by muse, mutect2
- CC2D2A | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs374554530; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHRND | c.1411C>T p.R471C | Missense Mutation (SNP) | VAF 67/134 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs533115724; called by muse, mutect2, varscan2
- COPS5 | c.526A>G p.I176V | Missense Mutation (SNP) | VAF 71/131 reads (54%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs369630651; called by muse, mutect2, varscan2
- CRYZ | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 25/534 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs1243277468; called by muse, mutect2
- CYLD | c.327G>T p.R109S | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100282209; called by muse, mutect2, varscan2
- DCAF8L1 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.831); catalogued as rs769053531, COSV71595254, COSV71595276; called by muse, mutect2, varscan2
- DYNC2H1 | c.5750G>A p.R1917Q | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as rs766435315; called by muse, mutect2, varscan2
- ERICH3 | c.2827G>C p.G943R | Missense Mutation (SNP) | VAF 37/307 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs764159125, COSV58602064; called by muse, mutect2, varscan2
- GALNTL6 | c.106C>A p.L36M | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.564); catalogued as COSV101550714; called by muse, mutect2, varscan2
- GIMAP1 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 46/479 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV100212318; called by muse, mutect2
- IGHV2-70 | c.287A>C p.K96T | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs138836314; called by muse, varscan2
- IGHV2-70 | c.206T>C p.L69P | Missense Mutation (SNP) | VAF 81/150 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as rs578104643; called by muse, varscan2
- IGHV2-70 | c.127T>C p.F43L | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs374779982; called by muse, varscan2
- IGHV2-70D | c.310A>C p.T104P | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1449320133; called by muse, varscan2
- IGHV2-70D | c.230A>G p.D77G | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs1466061529; called by muse, varscan2
- IGKV4-1 | c.153C>G p.Y51* | Nonsense Mutation (SNP) | VAF 54/57 reads (95%) | catalogued as rs762957191; called by muse, mutect2, varscan2
- IGLV3-1 | c.143A>T p.D48V | Missense Mutation (SNP) | VAF 88/148 reads (59%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as rs1426539348; called by muse, varscan2
- IGLV3-1 | c.290A>C p.Q97P | Missense Mutation (SNP) | VAF 82/157 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs372648481; called by muse, varscan2
- IGLV3-1 | c.295A>G p.M99V | Missense Mutation (SNP) | VAF 70/157 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs61731681; called by muse, varscan2
- IRF4 | c.176A>G p.K59R | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV66704473; called by muse, mutect2, varscan2
- OR2H1 | c.930G>T p.R310S | Missense Mutation (SNP) | VAF 12/330 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV65811115; called by muse, mutect2
- OTOP1 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs537569170, COSV56393346; called by muse, mutect2, varscan2
- PLG | c.2317A>G p.I773V | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.83); PolyPhen benign (0.015); catalogued as rs755235233; called by muse, mutect2, varscan2
- SEMA3A | c.1451G>T p.R484L | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV99548121; called by muse, mutect2, varscan2
- SH3RF3 | c.1612G>A p.V538I | Missense Mutation (SNP) | VAF 120/249 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs769131079; called by muse, mutect2, varscan2
- SLC7A2 | c.1906C>T p.Q636* (on ENST00000494857 / NM_001370338.1; = p.Q675* on NM_003046.6) | Nonsense Mutation (SNP) | VAF 22/282 reads (8%) | catalogued as rs930882332; called by muse, mutect2
- TRAF2 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 20/216 reads (9%) | catalogued as COSV56042757; called by muse, mutect2
- TRMT44 | c.2161T>C p.F721L | Missense Mutation (SNP) | VAF 177/338 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV67663370; called by muse, mutect2, varscan2
- ALOX5 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 80/194 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- BDNF | c.367T>G p.S123A | Missense Mutation (SNP) | VAF 12/255 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2
- BICRAL | c.3226A>G p.I1076V | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- CARD6 | c.2900C>T p.P967L | Missense Mutation (SNP) | VAF 203/446 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CHSY3 | c.2608G>A p.E870K | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2
- DHFR2 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.181); called by muse, mutect2
- ENPP3 | c.1982T>C p.V661A | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- FAM120B | c.2212G>A p.D738N | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FNDC1 | c.1483G>C p.A495P | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- GUCY1A2 | c.1398G>T p.K466N | Missense Mutation (SNP) | VAF 99/187 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IGHV2-70D | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 70/178 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, varscan2
- IGLV3-1 | c.301G>C p.E101Q | Missense Mutation (SNP) | VAF 72/156 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); called by muse, varscan2
- JAKMIP1 | c.2446T>C p.F816L | Missense Mutation (SNP) | VAF 32/364 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.916); called by muse, mutect2
- KCNA3 | c.1630del p.Q544Rfs*35 | Frame Shift Del (DEL) | VAF 67/189 reads (35%) | called by mutect2, pindel, varscan2
- MYF6 | c.581C>A p.S194Y | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.401); called by muse, mutect2
- MYO7B | c.2113G>A p.G705S | Missense Mutation (SNP) | VAF 31/292 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.084); called by muse, mutect2
- OR2W3 | c.133A>C p.I45L | Missense Mutation (SNP) | VAF 13/310 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- OR51C1P | c.470C>T p.T157I | Missense Mutation (SNP) | VAF 95/194 reads (49%) | SIFT tolerated (0.78); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PFAS | c.1764C>A p.F588L | Missense Mutation (SNP) | VAF 17/186 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.125); called by muse, mutect2
- PHF2 | c.3124C>A p.Q1042K | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT tolerated (0.96); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PIKFYVE | c.2608A>T p.I870L | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- PRAMEF1 | c.857A>C p.Q286P | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.009); called by mutect2, varscan2
- PRAMEF12 | c.1335G>T p.Q445H | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PSMD14 | c.229_230del p.Q77Vfs*11 | Frame Shift Del (DEL) | VAF 68/193 reads (35%) | called by pindel, varscan2
- RBM26 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- RTL9 | c.3191C>G p.T1064R | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- SNRNP25 | c.308A>T p.E103V (on ENST00000383018; = p.E94V on NM_024571.4) | Missense Mutation (SNP) | VAF 103/261 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- STARD8 | c.2153T>A p.L718Q | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SYTL5 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.028); called by muse, mutect2
- TAS2R3 | c.272T>C p.F91S | Missense Mutation (SNP) | VAF 27/281 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TOP1MT | c.1280C>T p.T427I | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRIM50 | c.389G>T p.S130I | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.033); called by muse, mutect2
- ZCCHC8 | c.732+2T>A p.X244_splice | Splice Site (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- ZNF816 | c.1207G>A p.D403N | Missense Mutation (SNP) | VAF 88/182 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- ABCA8 | c.1884C>T p.I628= | Silent (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- C1orf94 | c.1779G>A p.G593= (on ENST00000488417 / NM_001134734.2; = p.G403= on NM_032884.5) | Silent (SNP) | VAF 28/236 reads (12%) | catalogued as COSV64913113; called by muse, mutect2, varscan2
- CCDC185 | c.408G>A p.P136= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as rs771441338; called by muse, mutect2, varscan2
- CD300LF | c.732G>A p.K244= | Silent (SNP) | VAF 10/309 reads (3%) | called by muse, mutect2
- CDKL3 | c.448C>T p.L150= | Silent (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- COBLL1 | c.3486G>A p.L1162= (on ENST00000392717; = p.L1124= on NM_014900.5) | Silent (SNP) | VAF 84/217 reads (39%) | called by muse, mutect2, varscan2
- COL4A2 | c.1305A>T p.G435= | Silent (SNP) | VAF 55/125 reads (44%) | called by muse, mutect2, varscan2
- EEPD1 | c.996C>T p.C332= | Silent (SNP) | VAF 10/148 reads (7%) | called by muse, mutect2
- FLRT3 | c.972T>A p.P324= | Silent (SNP) | VAF 72/162 reads (44%) | called by muse, mutect2, varscan2
- HPN | c.252G>A p.R84= | Silent (SNP) | VAF 55/118 reads (47%) | called by muse, mutect2, varscan2
- IGKJ1 | c.18A>G p.Q6= | Silent (SNP) | VAF 182/196 reads (93%) | catalogued as rs767206731; called by muse, mutect2, varscan2
- IGLL5 | c.9C>T p.P3= | Silent (SNP) | VAF 42/92 reads (46%) | called by muse, mutect2, varscan2
- IGLV3-1 | c.69G>C p.L23= | Silent (SNP) | VAF 61/145 reads (42%) | catalogued as rs548728259; called by muse, mutect2, varscan2
- MEFV | c.2109C>T p.S703= | Silent (SNP) | VAF 49/475 reads (10%) | catalogued as rs104895118, CM035565; ClinVar: likely benign; called by muse, mutect2, varscan2
- MGAM | c.2895C>T p.D965= | Silent (SNP) | VAF 49/76 reads (64%) | called by muse, mutect2, varscan2
- MYF6 | c.582C>T p.S194= | Silent (SNP) | VAF 14/209 reads (7%) | called by muse, mutect2
- NOSTRIN | c.904C>T p.L302= (on ENST00000317647 / NM_001039724.4; = p.L224= on NM_052946.3) | Silent (SNP) | VAF 6/77 reads (8%) | called by muse, mutect2
- PTGDR | c.732C>T p.A244= | Silent (SNP) | VAF 34/79 reads (43%) | called by muse, mutect2, varscan2
- RBMXL3 | c.1737C>T p.S579= | Silent (SNP) | VAF 8/129 reads (6%) | catalogued as rs1392572543; called by muse, mutect2
- RHAG | c.870A>C p.A290= | Silent (SNP) | VAF 12/173 reads (7%) | catalogued as COSV57704079; called by muse, mutect2
- RIF1 | c.120A>G p.E40= | Silent (SNP) | VAF 25/57 reads (44%) | called by muse, mutect2, varscan2
- RIMBP2 | c.466C>A p.R156= | Silent (SNP) | VAF 87/90 reads (97%) | catalogued as COSV55480180; called by muse, mutect2, varscan2
- TMEM260 | c.1461T>C p.P487= | Silent (SNP) | VAF 22/276 reads (8%) | called by muse, mutect2
- TOGARAM1 | c.849T>C p.I283= | Silent (SNP) | VAF 12/183 reads (7%) | called by muse, mutect2
- TTN | c.26496C>G p.G8832= (on ENST00000591111; = p.G7905= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/227 reads (5%) | called by muse, mutect2
- ABL2 | c.*3361G>C | 3'UTR (SNP) | VAF 11/110 reads (10%) | called by muse, mutect2, varscan2
- ADGRG2 | chrX:18984415 G>A | 3'Flank (SNP) | VAF 32/33 reads (97%) | called by muse, mutect2, varscan2
- ADH7 | c.*66C>T | 3'UTR (SNP) | VAF 48/678 reads (7%) | catalogued as rs1325965648; called by muse, mutect2
- AL162726.3 | n.255+82968T>C | Intron (SNP) | VAF 24/69 reads (35%) | called by muse, mutect2, varscan2
- ANKRD23 | c.*331A>G | 3'UTR (SNP) | VAF 113/261 reads (43%) | called by muse, mutect2, varscan2
- AP001993.1 | chr11:127101162 A>C | 3'Flank (SNP) | VAF 36/83 reads (43%) | called by muse, mutect2, varscan2
- APOL2 | c.*605G>A | 3'UTR (SNP) | VAF 15/334 reads (4%) | called by muse, mutect2
- ATF6B | c.1153-22T>C | Intron (SNP) | VAF 73/223 reads (33%) | called by muse, mutect2, varscan2
- BCL7C | c.*303C>T | 3'UTR (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- BTBD11 | c.*1844G>A | 3'UTR (SNP) | VAF 10/64 reads (16%) | catalogued as rs1009229633; called by muse, mutect2, varscan2
- C19orf81 | c.*8G>A | 3'UTR (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- CADPS2 | c.*392G>C | 3'UTR (SNP) | VAF 73/141 reads (52%) | called by muse, mutect2, varscan2
- CAMK4 | c.*6387A>C | 3'UTR (SNP) | VAF 16/119 reads (13%) | called by muse, mutect2, varscan2
- CAMLG | c.*328T>C | 3'UTR (SNP) | VAF 29/63 reads (46%) | called by muse, mutect2, varscan2
- CCN3 | c.-45C>T | 5'UTR (SNP) | VAF 40/93 reads (43%) | called by muse, mutect2, varscan2
- CCND1 | c.-70_-55del | 5'UTR (DEL) | VAF 13/31 reads (42%) | called by mutect2, pindel, varscan2
- CDH7 | chr18:65881628 T>A | 3'Flank (SNP) | VAF 9/119 reads (8%) | called by muse, mutect2
- CNBD1 | c.*14C>A | 3'UTR (SNP) | VAF 6/40 reads (15%) | catalogued as COSV101582166, COSV73073518; called by muse, mutect2, varscan2
- CXADR | c.*2344T>C | 3'UTR (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2
- DACH2 | c.1751-902A>T | Intron (SNP) | VAF 13/74 reads (18%) | called by muse, mutect2, varscan2
- DCAF8L1 | c.*566G>A | 3'UTR (SNP) | VAF 8/164 reads (5%) | catalogued as COSV101491542; called by muse, mutect2
- DLAT | c.*580G>C | 3'UTR (SNP) | VAF 17/165 reads (10%) | called by muse, mutect2, varscan2
- DPP9 | c.1798+50A>G | Intron (SNP) | VAF 8/12 reads (67%) | called by muse, mutect2, varscan2
- EDIL3 | c.-49C>T | 5'UTR (SNP) | VAF 7/173 reads (4%) | called by muse, mutect2
- EEF1A2 | c.1029+162C>T | Intron (SNP) | VAF 11/37 reads (30%) | catalogued as rs903057706, COSV53207941; called by muse, mutect2, varscan2
- FAM120AOS | c.564-448T>A | Intron (SNP) | VAF 38/446 reads (9%) | called by muse, mutect2
- FAM13A | c.759+166T>G | Intron (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- FIGN | c.*4232G>C | 3'UTR (SNP) | VAF 41/92 reads (45%) | called by muse, mutect2, varscan2
- FOXO6 | chr1:41382981 G>A | 3'Flank (SNP) | VAF 31/58 reads (53%) | called by muse, mutect2, varscan2
- FUBP3 | c.-18_-4del | 5'UTR (DEL) | VAF 12/30 reads (40%) | catalogued as rs1051186096; called by mutect2, varscan2
- GDE1 | c.-97C>T | 5'UTR (SNP) | VAF 12/92 reads (13%) | called by muse, mutect2, varscan2
- GFM1 | c.1764+185A>C | Intron (SNP) | VAF 25/49 reads (51%) | called by muse, mutect2, varscan2
- HDX | c.*1865T>G | 3'UTR (SNP) | VAF 40/40 reads (100%) | called by muse, mutect2, varscan2
- IYD | c.*1601C>T | 3'UTR (SNP) | VAF 23/23 reads (100%) | called by mutect2, varscan2
- KDM7A | c.*5174A>C | 3'UTR (SNP) | VAF 43/100 reads (43%) | called by muse, mutect2, varscan2
- KIF1B | c.2115+7309C>T | Intron (SNP) | VAF 90/169 reads (53%) | catalogued as rs143359582; called by muse, mutect2, varscan2
- LIMD2 | c.43-33G>C | Intron (SNP) | VAF 19/41 reads (46%) | called by muse, mutect2, varscan2
- LINC01567 | n.67G>A | RNA (SNP) | VAF 93/211 reads (44%) | called by muse, mutect2, varscan2
- LONRF2 | c.*6743A>C | 3'UTR (SNP) | VAF 7/129 reads (5%) | called by muse, mutect2
- LPAR1 | chr9:110873389 A>G | 3'Flank (SNP) | VAF 5/123 reads (4%) | called by muse, mutect2
- LUZP2 | c.*1560G>C | 3'UTR (SNP) | VAF 10/75 reads (13%) | called by muse, mutect2, varscan2
- MAGEC3 | c.1124-260G>T | Intron (SNP) | VAF 23/134 reads (17%) | called by muse, mutect2, varscan2
- MALT1 | c.*3610A>G | 3'UTR (SNP) | VAF 20/54 reads (37%) | called by muse, mutect2, varscan2
- MIEN1 | c.187+17A>G | Intron (SNP) | VAF 152/309 reads (49%) | catalogued as rs1214106090; called by muse, mutect2, varscan2
- MIR124-2 | chr8:64378397 G>T | 5'Flank (SNP) | VAF 70/138 reads (51%) | called by muse, mutect2, varscan2
- NDUFS3 | c.381+105A>C | Intron (SNP) | VAF 13/80 reads (16%) | called by muse, mutect2, varscan2
- NEK10 | c.569-125T>C | Intron (SNP) | VAF 11/74 reads (15%) | called by muse, mutect2
- NFS1 | c.97+181C>T | Intron (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
- PBX1 | c.*3800_*3801insT | 3'UTR (INS) | VAF 5/57 reads (9%) | called by mutect2, pindel
- PRKAB2 | c.*4039G>T | 3'UTR (SNP) | VAF 6/65 reads (9%) | called by muse, mutect2
- PROS1 | c.*678T>C | 3'UTR (SNP) | VAF 69/153 reads (45%) | called by muse, mutect2, varscan2
- PTPRE | c.*2101C>G | 3'UTR (SNP) | VAF 46/489 reads (9%) | called by muse, mutect2
- PXDN | c.2104+364C>T | Intron (SNP) | VAF 106/231 reads (46%) | catalogued as rs1441446508; called by muse, mutect2, varscan2
- RAB6D | c.*1273T>A | 3'UTR (SNP) | VAF 108/253 reads (43%) | catalogued as COSV72151692; called by muse, mutect2, varscan2
- RALGAPA2 | c.5495+502G>A | Intron (SNP) | VAF 12/210 reads (6%) | called by muse, mutect2
- RBM46 | c.1403-317C>T | Intron (SNP) | VAF 6/126 reads (5%) | catalogued as rs867398477; called by muse, mutect2
- RNH1 | c.444-205G>A | Intron (SNP) | VAF 5/34 reads (15%) | catalogued as rs537939234; called by muse, mutect2
- RRP8 | c.*1569C>T | 3'UTR (SNP) | VAF 9/165 reads (5%) | called by muse, mutect2
- RUNX1T1 | c.*3364G>A | 3'UTR (SNP) | VAF 30/69 reads (43%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.*1033C>T | 3'UTR (SNP) | VAF 8/83 reads (10%) | called by muse, mutect2
- SEMA3A | c.*2565C>G | 3'UTR (SNP) | VAF 31/90 reads (34%) | called by muse, mutect2, varscan2
- SLC12A1 | c.*855G>A | 3'UTR (SNP) | VAF 7/96 reads (7%) | called by muse, mutect2
- SRGAP1 | c.*514T>A | 3'UTR (SNP) | VAF 12/123 reads (10%) | called by muse, mutect2, varscan2
- STK10 | c.*351C>A | 3'UTR (SNP) | VAF 23/235 reads (10%) | called by muse, mutect2, varscan2
- SVIP | c.*1724G>C | 3'UTR (SNP) | VAF 37/67 reads (55%) | called by muse, mutect2, varscan2
- SYT16 | c.*94C>T | 3'UTR (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- TAX1BP3 | c.*154C>T | 3'UTR (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- TECRL | chr4:64276589 C>G | 3'Flank (SNP) | VAF 33/88 reads (38%) | called by muse, mutect2
- TECRL | c.*106T>C | 3'UTR (SNP) | VAF 21/43 reads (49%) | called by muse, mutect2, varscan2
- TIMM17B | c.127-260G>T | Intron (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2, varscan2
- TMTC1 | c.*4028C>T | 3'UTR (SNP) | VAF 40/88 reads (45%) | called by muse, mutect2, varscan2
- TPO | c.2749-114G>T | Intron (SNP) | VAF 16/138 reads (12%) | called by muse, mutect2, varscan2
- TSPAN14 | chr10:80519491 T>A | 3'Flank (SNP) | VAF 58/102 reads (57%) | called by muse, varscan2
- TTN | c.38290+49C>T | Intron (SNP) | VAF 10/226 reads (4%) | called by muse, mutect2
- TULP1 | c.*253G>T | 3'UTR (SNP) | VAF 11/293 reads (4%) | called by muse, mutect2
- TYW5 | c.*1103C>T | 3'UTR (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- UBA6 | c.*324A>G | 3'UTR (SNP) | VAF 21/48 reads (44%) | called by muse, mutect2
- UBA6 | c.*177A>C | 3'UTR (SNP) | VAF 54/117 reads (46%) | called by muse, mutect2, varscan2
- USF3 | c.*1093A>C | 3'UTR (SNP) | VAF 19/45 reads (42%) | called by muse, mutect2, varscan2
- VCPIP1 | c.-243G>A | 5'UTR (SNP) | VAF 15/263 reads (6%) | called by muse, mutect2
- XIRP2 | c.*1509A>C | 3'UTR (SNP) | VAF 16/548 reads (3%) | called by muse, mutect2
- ZDHHC22 | c.*2024G>A | 3'UTR (SNP) | VAF 5/116 reads (4%) | catalogued as rs1448034922; called by muse, mutect2
- ZNF493 | c.*1423G>C | 3'UTR (SNP) | VAF 10/83 reads (12%) | called by muse, mutect2, varscan2
